Somatic mutation profile of tumor specimen TCGA-CK-4948-01B (aliquot TCGA-CK-4948-01B-11D-1650-10) from TCGA case TCGA-CK-4948, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage III; Age at diagnosis: 45.8 years (16,736 days).
Specimen TCGA-CK-4948-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51f15968-d2a1-4531-88ad-62ffcb604113.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-4948-10A (Blood Derived Normal), aliquot TCGA-CK-4948-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e18a5952-1815-4265-844a-8ae8e2ab3680

The open-access MAF lists 110 somatic variants for this specimen: 87 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 22, Nonsense Mutation 10, Splice Site 2, Intron 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs199472713, CD097162, CM002323, CM0910334, COSV50117931; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 115/355 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SMAD3 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 27/42 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs794727798, COSV59282451; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 31/51 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AMY1C | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs201967863, COSV64407042; called by muse, mutect2, varscan2
- ANKRD50 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.067); catalogued as COSV101539030, COSV72385912; called by muse, mutect2, varscan2
- ANXA1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs142849845; called by muse, mutect2
- APC | c.3175G>T p.E1059* | Nonsense Mutation (SNP) | VAF 47/219 reads (21%) | catalogued as CM016190, COSV57323783; called by muse, mutect2, varscan2
- CACNA1I | c.5954T>C p.L1985P | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV60813220; called by muse, mutect2, varscan2
- CFAP100 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.884); catalogued as rs767440483, COSV100729155; called by muse, mutect2, varscan2
- CFAP47 | c.4753A>T p.N1585Y | Missense Mutation (SNP) | VAF 40/607 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV100545200; called by muse, mutect2
- CRTAC1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs369926645; called by muse, mutect2, varscan2
- DCP2 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 17/309 reads (6%) | catalogued as COSV101203869; called by muse, mutect2
- DNAH3 | c.4202G>A p.R1401Q | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879199308, COSV99766366; called by muse, mutect2, varscan2
- DYNC2I1 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 128/455 reads (28%) | catalogued as COSV68105836; called by muse, mutect2, varscan2
- EFCAB12 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs371215765; called by muse, mutect2, varscan2
- EPHA5 | c.1031G>C p.R344T | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV56631762, COSV56656573; called by muse, mutect2
- ERICH3 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 36/934 reads (4%) | catalogued as COSV100443944; called by muse, mutect2
- FAM171B | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV100488456, COSV100488805, COSV59001118; called by muse, mutect2, varscan2
- FBXW7 | c.572C>G p.S191* (on ENST00000281708 / NM_001349798.2; = p.S111* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 303/833 reads (36%) | catalogued as COSV99656056; called by muse, mutect2, varscan2
- FLRT2 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755015167, COSV58138258; called by muse, mutect2, varscan2
- FOXI1 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435895089, COSV60388712; called by muse, mutect2, varscan2
- FUS | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 30/210 reads (14%) | catalogued as COSV54218523; called by muse, mutect2, varscan2
- FZD10 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57475026; called by muse, mutect2, varscan2
- GUCY2F | c.3055+1G>A p.X1019_splice | Splice Site (SNP) | VAF 38/222 reads (17%) | catalogued as rs773169093, COSV99484793; called by muse, varscan2
- IDH2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57477190; called by muse, mutect2, varscan2
- IPO7 | c.2013G>C p.M671I | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63352782; called by muse, mutect2, varscan2
- ITGA1 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs754569096, COSV50887190; called by muse, mutect2, varscan2
- ITGAV | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 86/361 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1424844364, COSV53715501, COSV53717195; called by muse, mutect2, varscan2
- KRTAP13-2 | c.10A>C p.N4H | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV67762143; called by muse, mutect2, varscan2
- LDLRAD3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs751951395, COSV59683659; called by muse, mutect2, varscan2
- LRP5 | c.1427C>A p.T476K | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99591759; called by muse, mutect2, varscan2
- LRRC37B | c.2078C>A p.T693K | Missense Mutation (SNP) | VAF 777/1949 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58953400; called by muse, mutect2, varscan2
- LSAMP | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.15); catalogued as rs569392861, COSV61288765; called by muse, mutect2, varscan2
- MAP3K6 | c.3455C>T p.P1152L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs762693057, COSV100539259; called by muse, mutect2, varscan2
- MDH2 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59884702; called by muse, mutect2, varscan2
- MFSD14B | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 107/698 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as rs774933529, COSV100942597; called by muse, varscan2
- MUC16 | c.7928T>A p.L2643* | Nonsense Mutation (SNP) | VAF 58/139 reads (42%) | catalogued as COSV67478310; called by muse, mutect2, varscan2
- NEB | c.20003C>T p.A6668V | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51433962; called by muse, mutect2, varscan2
- NLGN4X | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 95/524 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs754987934, COSV52009814; called by muse, mutect2, varscan2
- NLRP7 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs771101644, COSV60171092; called by muse, mutect2, varscan2
- NOMO1 | c.2940G>A p.M980I | Missense Mutation (SNP) | VAF 102/917 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99814382; called by muse, mutect2, varscan2
- NPR2 | c.3094C>T p.R1032* | Nonsense Mutation (SNP) | VAF 42/85 reads (49%) | catalogued as COSV52414403; called by muse, mutect2, varscan2
- NPY2R | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764371059, COSV61527463; called by muse, mutect2, varscan2
- NUP214 | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.234); catalogued as COSV63911078; called by muse, mutect2, varscan2
- OBSCN | c.23362C>A p.L7788M | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100803009; called by muse, mutect2, varscan2
- OFD1 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 152/909 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1569141112, COSV60797164; called by muse, mutect2, varscan2
- OR4C13 | c.271T>A p.L91I | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as COSV101634159; called by muse, mutect2
- OR5L2 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65724552; called by muse, mutect2, varscan2
- OR6A2 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV60265361; called by muse, mutect2, varscan2
- OR8K3 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); catalogued as COSV57132158; called by muse, mutect2, varscan2
- OTOF | c.2272C>T p.R758C (on ENST00000272371 / NM_194248.3; = p.R11C on NM_004802.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs368186242; called by muse, mutect2, varscan2
- PCDHGA10 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV53983509; called by muse, mutect2, varscan2
- PCLO | c.4117T>A p.S1373T | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61648328; called by muse, mutect2, varscan2
- PLEC | c.9688G>T p.E3230* (on ENST00000322810 / NM_201380.4; = p.E3120* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as rs868974777, COSV100510034, COSV59658748; called by muse, mutect2, varscan2
- PNPLA8 | c.33T>G p.I11M | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV57553623; called by muse, mutect2, varscan2
- PRG4 | c.1280C>A p.S427Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV100798167; called by muse, varscan2
- PSD2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); catalogued as rs760999431, COSV51203854; called by muse, mutect2, varscan2
- REM2 | c.308C>A p.S103* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV57465762; called by muse, mutect2, varscan2
- ROS1 | c.1164+2T>C p.X388_splice | Splice Site (SNP) | VAF 8/135 reads (6%) | catalogued as COSV100876893; called by muse, mutect2
- SAGE1 | c.254G>T p.R85M | Missense Mutation (SNP) | VAF 22/594 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100187002, COSV61016609; called by muse, mutect2
- SEC23IP | c.1980A>C p.E660D | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as COSV64832164; called by muse, mutect2, varscan2
- SGK1 | c.1064_1066del p.F355del | In Frame Del (DEL) | VAF 18/112 reads (16%) | catalogued as rs1562235638; called by pindel, varscan2
- SLC13A1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766787346, COSV52013916; called by muse, mutect2, varscan2
- SORCS1 | c.2792C>T p.T931M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs1342440262, COSV53884194; called by muse, mutect2, varscan2
- SOS1 | c.2864T>C p.L955P | Missense Mutation (SNP) | VAF 177/594 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67676370; called by muse, mutect2, varscan2
- SPINK5 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 112/424 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56258119; called by muse, mutect2, varscan2
- SPTA1 | c.4039G>A p.A1347T | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV63756362; called by muse, mutect2, varscan2
- TACR1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs749162463, COSV59481398; called by muse, mutect2, varscan2
- TAF2 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.569); catalogued as COSV65419270; called by muse, mutect2, varscan2
- TEX11 | c.1781C>T p.P594L (on ENST00000344304; = p.P579L on NM_031276.3) | Missense Mutation (SNP) | VAF 35/698 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.397); catalogued as rs770614604, COSV100721539; called by muse, mutect2
- TKFC | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779478150, COSV67523856; called by muse, mutect2, varscan2
- TRIM26 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1562215626, COSV68963203; called by muse, mutect2, varscan2
- UBE2O | c.3642C>A p.D1214E | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.083); catalogued as COSV100039262; called by muse, mutect2, varscan2
- UBQLNL | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 131/523 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs150209910; called by muse, mutect2, varscan2
- UNC5C | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs139372477; called by muse, mutect2, varscan2
- UNC5D | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448247097, COSV54811272, COSV54846645; called by muse, mutect2, varscan2
- YY2 | c.608A>T p.Q203L | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.276); catalogued as COSV63412045; called by muse, mutect2, varscan2
- ZC3H7A | c.2057A>T p.E686V | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV63270379; called by muse, mutect2, varscan2
- ZNF35 | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1445332843, COSV56077001; called by muse, mutect2
- ZNF35 | c.1552A>C p.M518L | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.029); catalogued as rs1312481377, COSV56077010; called by muse, mutect2, varscan2
- ZNF385D | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1034519990, COSV55752967; called by muse, mutect2, varscan2
- ZNF423 | c.3839C>G p.T1280S (on ENST00000563137 / NM_001379286.1; = p.T1272S on NM_015069.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.703); catalogued as COSV99280960; called by muse, mutect2, varscan2
- ZNF674 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 122/276 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70379302; called by muse, mutect2, varscan2
- CYLC1 | c.1197T>G p.D399E | Missense Mutation (SNP) | VAF 13/319 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.257); called by muse, mutect2
- DMRTA2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- INSRR | c.1661_1665del p.R554Pfs*28 | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.1815C>T p.Y605= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs369654932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANGEL2 | c.1434G>A p.V478= | Silent (SNP) | VAF 128/356 reads (36%) | catalogued as COSV64737695; called by muse, mutect2, varscan2
- APOB | c.4251G>A p.T1417= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as rs72653082, COSV51942854, COSV99264051; ClinVar: likely benign; called by muse, mutect2, varscan2
- BMP7 | c.1050G>A p.A350= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs775245192, COSV67781526; called by muse, mutect2, varscan2
- CCDC60 | c.438C>T p.T146= | Silent (SNP) | VAF 60/168 reads (36%) | catalogued as rs1279207572, COSV59546749; called by muse, mutect2, varscan2
- CHST2 | c.1131C>T p.G377= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV100535818; called by muse, mutect2
- CYP2A7 | c.402C>A p.T134= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV52503239; called by muse, mutect2, varscan2
- DAG1 | c.1341C>A p.R447= | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as COSV58185586; called by muse, mutect2, varscan2
- EFS | c.444C>T p.Y148= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs547155652, COSV53733659; called by muse, mutect2
- FMR1 | c.1374A>G p.E458= | Silent (SNP) | VAF 41/355 reads (12%) | catalogued as COSV54425534; called by muse, mutect2, varscan2
- GBE1 | c.450C>T p.S150= | Silent (SNP) | VAF 34/316 reads (11%) | catalogued as rs766421967, COSV70096811, COSV70100894; called by muse, mutect2, varscan2
- GYG2 | c.1023G>A p.P341= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs765965808, COSV58550817; called by muse, mutect2, varscan2
- IRAK1 | c.513G>A p.P171= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV57655302; called by muse, mutect2, varscan2
- KRAS | c.105A>C p.T35= | Silent (SNP) | VAF 64/216 reads (30%) | catalogued as COSV55860510; called by muse, varscan2
- LTBP2 | c.135G>A p.P45= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs372107387, COSV100000080; called by muse, mutect2, varscan2
- MOV10L1 | c.390C>T p.G130= | Silent (SNP) | VAF 98/270 reads (36%) | catalogued as rs763137022, COSV53167626; called by muse, mutect2, varscan2
- PAX7 | c.1386C>T p.Y462= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs570561092, COSV64751276; called by muse, mutect2, varscan2
- SPAG17 | c.4632T>C p.C1544= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV60462718; called by muse, mutect2, varscan2
- SVEP1 | c.5238C>T p.V1746= | Silent (SNP) | VAF 89/220 reads (40%) | catalogued as rs748655768, COSV52841258; called by muse, mutect2, varscan2
- TRIM39 | c.735C>T p.A245= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as COSV64955175; called by muse, mutect2, varscan2
- TTC25 | c.219G>A p.S73= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as rs377117826; called by muse, mutect2, varscan2
- USP45 | c.840T>C p.C280= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV100328112; called by muse, mutect2
- KIF1B | c.2115+7032C>G | Intron (SNP) | VAF 25/71 reads (35%) | catalogued as COSV55811597; called by muse, mutect2, varscan2
